Somatic mutation profile of tumor specimen BA2618D (aliquot aq-BA2618D) from BEATAML1.0 case 2498, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.0 years (30,330 days).
Specimen BA2618D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8c6067e-6197-492d-90b6-f17918209740.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2323D (Solid Tissue Normal), aliquot aq-BA2323D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db7a5732-d97c-4d02-b694-0f1afa025e46

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PUF60 | c.389G>A p.R130H (on ENST00000526683 / NM_001362896.2; = p.R113H on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1554643584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CASS4 | c.2335C>T p.R779W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1435693423; called by muse, mutect2, varscan2
- H3C3 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63551114; called by muse, mutect2, varscan2
- ITGA8 | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs768261688, COSV65225574; called by muse, mutect2, varscan2
- VWA3B | c.3634G>A p.A1212T | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs759687874; called by muse, varscan2
- ARHGAP30 | c.1252G>T p.V418F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- DNAJB2 | c.444C>A p.S148= | Splice Region (SNP) | VAF 14/30 reads (47%) | called by muse, varscan2
- IFT172 | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 73/155 reads (47%) | called by muse, mutect2, varscan2
- OR4D5 | c.810C>A p.A270= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100189713, COSV58306193; called by muse, mutect2
